CCDI case PBBSDA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/bfce6f2a-dbb7-4879-aedc-69829e1eb485

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Prostate gland; Age at diagnosis: 6.5 years (2,379 days).

Biospecimens (3 samples)
- Sample 0DFO12: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFO1F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFO1S: Tissue type: Tumor; Specimen type: Solid Tissue.
